Somatic mutation profile of tumor specimen TCGA-FB-A4P6-01A (aliquot TCGA-FB-A4P6-01A-12D-A26I-08) from TCGA case TCGA-FB-A4P6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 54.5 years (19,904 days).
Specimen TCGA-FB-A4P6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a13597cb-d825-406a-96ba-d58af981464f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-A4P6-10A (Blood Derived Normal), aliquot TCGA-FB-A4P6-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/703cc132-52b0-49f5-ab47-e7c0c78c5db3

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPP1 | c.2148T>C p.Y716= (on ENST00000676605; = p.Y675= on NM_024790.6) | Silent (SNP) | VAF 34/1079 reads (3%) | catalogued as COSV99139249; called by muse, mutect2
